Gene-level copy-number profile of tumor specimen TCGA-BB-7870-01A from TCGA case TCGA-BB-7870, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 58.7 years (21,443 days).
Specimen TCGA-BB-7870-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.db34b341-6222-498c-ab19-77bc8d9f5710.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BB-7870-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9db1d4a0-e61e-4723-9573-212816690835

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 119; copy number 2: 4,009; copy number 3: 17,389; copy number 4: 22,308; copy number 5: 13,189; copy number 6: 1,798; copy number 7: 393; copy number 8: 248; copy number 9: 161; copy number 11: 114; copy number 12: 10; copy number 13: 21; copy number 18: 12; copy number 35: 44.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BB-7870-01A-11D-2228-01): tumor purity 0.71, ploidy 3.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 119 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,386,927–27,297,150, 118 genes (broad region; genes not listed).
- chr9:27,391,734–27,397,563, 1 gene: AL163192.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 362 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:87,261,931–89,999,409, 63 genes, copy number 9 (broad region; genes not listed).
- chr4:90,370,123–90,370,427, 1 gene, copy number 9: RN7SKP248.
- chr9:14,475–215,893, 9 genes, copy number 12: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1.
- chr9:267,966–273,002, 1 gene, copy number 12: AL158832.1.
- chr9:33,503,655–35,405,338, 97 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr11:69,147,228–70,436,584, 38 genes, copy number 35: AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,706,068, 6 genes, copy number 35: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr18:47,390–3,247,277, 73 genes, copy number 11–18 (within-gene range 5–18) (broad region; genes not listed).
- chr18:3,284,120–3,478,978, 8 genes, copy number 13 (within-gene range 5–13): AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:3,571,215–3,656,282, 5 genes, copy number 13: RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1.
- chr18:8,360,820–8,406,953, 3 genes, copy number 13: AP001094.3, AP001094.2, AP001094.1.
- chr18:10,666,483–11,149,569, 1 gene, copy number 13 (within-gene range 8–13): PIEZO2.
- chr18:10,893,617–11,390,729, 4 genes, copy number 13: AP005120.1, AP005139.1, AP005229.1, AP005229.2.
- chr18:14,010,054–15,330,282, 53 genes, copy number 11: AC006557.6, AC006557.5, ZNF519, AC006557.4, AC006557.1, AC006557.3, FRG2LP, AC006557.2, NF1P5, ANKRD20A5P, RNU6-316P, RHOT1P1, AP005212.4, AP005212.2, CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
